Surgical pathology report (de-identified scan), TCGA case TCGA-56-A4BW, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-A4BW-01A (Primary Tumor).

[page 1 of 2]
Surg Path Final Report

* Final Report *

ICD-0-3

carcinoma, squamous cell, NOS 8070/3

Site: lung, upper lobe c34.1

Result Type: Surg Path Final Report
Result Date:
Result Status: Auth (Verified)
Result Title: Surgical Pathology Final Report
Verified By:
Encounter info:

pw
9/26/12

* Final Report *

Final Diagnosis (Verified)

Left lung, pneumonectomy with frozen section examination:

Moderately differentiated squamous cell carcinoma within upper lobe.

Overlying pleural surface free of neoplasm.

Tumor measures 4.5 cm in maximum gross dimension.

Bronchial margins of surgical resection are free.

Hilar lymph nodes:

Two (2) of six (6) lymph nodes positive for metastatic squamous cell carcinoma.

Lymph node dissection:

4L lower paratracheal nodes:

One (1) negative node.

7 subcarinal lymph node:

Three (3) negative nodes.

8 paraesophageal below carina lymph nodes:

Seven (7) negative nodes.

9 pulmonary ligament lymph nodes:

Two (2) negative nodes.

Comment: This case corresponds to a pathological AJCC stage of T2a,N1.

Signature Line

(Electronically signed by)

Verified on:

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 2]
Surg Path Final Report

* Final Report *

Frozen Section Diagnosis (Verified)

History: Left lung mass.

Specimen A: Left pneumonectomy.

Gross A: Pleural surface over tumor inked.
Sectioning reveals 4.5 cm white mass.

FSA1: Tumor mass: Squamous cell carcinoma.

FSA2: Bronchial and vascular margins: No tumor

Clinical Information (Verified)

Left lung cancer.

Performing Lab (Verified)

Testing performed at

Gross Description (Verified)

"A, NFSA." Received after frozen section is a 349 gram, 18.7 x 12.3 x 5.8 cm left lung. The bronchial and vascular margins have been previously sampled. There is a 4.5 x 3.2 cm white-tan, firm mass in the upper lobe. The mass grossly appears to come to within 0.3 cm of the adjacent pleura. The pleura overlying the mass has been previously inked blue. The mass grossly appears to surround the intraparenchymal portion of the bronchus and comes to within 3.2 cm of the current bronchial margin. The remaining lung parenchyma ranges from pink-tan to congested. No other masses or lesions are grossly identified in the remainder of the lung. At the hilum of the lobe are 7 possible lymph nodes ranging from 0.4 to 1.8 cm in greatest dimension. Two portions of the specimen have been submitted for frozen section in cassettes "FSA1" and "FSA2." "A1-A3," random sections of the mass; "A4," random sections of the mass with adjacent intraparenchymal portion of bronchus; "A5," random sections remainder of lung; "A6-A7," possible hilar lymph nodes.

"B, 4L lower paratracheal." Received is a 2.1 x 1.3 x 0.5 cm black to tan lymph node. The lymph node will be bisected and submitted in toto. "B," all.

"C, 7 subcarinal." Received are 3 lymph nodes ranging from 0.5 to 1.1 cm. The specimen will be submitted in toto. "C," all.

"D, 8 paraesophageal below carina." Received are 7 possible lymph nodes ranging from 0.3 to 1.1 cm. All the lymph nodes will be submitted in toto. "D1," smaller lymph nodes; "D2," largest lymph node.

"E, 9 pulmonary ligament." Received are 3 lymph nodes ranging from 0.7 to 1.2 cm submitted in toto. "E," all.

Signature Line

Completed Action List:

Printed by:
Printed on:

Page 2 of 3
(Continued)

Prior Malignancy/History		X
Reviewed Initials	Date Reviewed: 9/4/12	

LMC

8/24/12

Source: NCI Genomic Data Commons file a69d5ede-eb5c-4838-b89f-f8d0f8b08b32 (TCGA-56-A4BW.8CC4BF2C-0E0E-4724-BC6C-6E317E0C5C5F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).